Somatic mutation profile of tumor specimen BA2369D (aliquot aq-BA2369D) from BEATAML1.0 case 2276, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.1 years (27,418 days).
Specimen BA2369D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2305c471-296b-4252-b5eb-4bb367916d99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2518D (Solid Tissue Normal), aliquot aq-BA2518D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f927b334-dee1-460f-97f9-1cf5ba582771

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 2, Splice Site 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.1049-5C>T | Splice Region (SNP) | VAF 12/30 reads (40%) | catalogued as rs759317623; called by muse, varscan2
- ATG2B | c.326-1G>T p.X109_splice | Splice Site (SNP) | VAF 5/63 reads (8%) | catalogued as COSV63426389; called by muse, mutect2
- LMX1B | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.931); catalogued as rs779417752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGTA | c.636+1G>T p.X212_splice | Splice Site (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99682693; called by muse, mutect2
- SOX17 | c.219C>A p.N73K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52025533, COSV52026919; called by muse, mutect2
- SLC23A1 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.133); called by muse, mutect2
- CLCN6 | c.2394C>A p.R798= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- ZNF524 | c.381C>A p.S127= | Silent (SNP) | VAF 3/53 reads (6%) | called by muse, mutect2
- CCNJL | chr5:160315488 C>A | 5'Flank (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- IGFN1 | c.1241+1628G>A | Intron (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2
- STXBP2 | c.246+75A>G | Intron (SNP) | VAF 30/84 reads (36%) | called by muse, varscan2
